Gene-level copy-number profile of specimen HCM-WCMC-0790-C67-85B from HCMI case HCM-WCMC-0790-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.4 years (22,784 days).
Specimen HCM-WCMC-0790-C67-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f825f9e5-1ee3-4a18-8106-43065a551f53.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0790-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/4c37e31b-72ec-4202-acb8-58fea622a14f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 5,545; copy number 3: 18,232; copy number 4: 18,660; copy number 5: 7,579; copy number 6: 4,838; copy number 7: 1,986; copy number 8: 660; copy number 9: 26; copy number 10: 1,332; copy number 11: 4; copy number 12: 12; copy number 13: 2; copy number 32: 20.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,396 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:19,837,370–21,602,383, 20 genes, copy number 32 (within-gene range 2–32): ID4, AL008627.1, MBOAT1, AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr8:56,776,283–145,066,685, 1,332 genes, copy number 10 (broad region; genes not listed).
- chr9:63,581,254–63,581,834, 1 gene, copy number 9: AL591438.1.
- chr9:65,189,995–65,230,861, 3 genes, copy number 11: BMS1P12, AL512605.1, AL512605.2.
- chr12:13,437,942–13,982,002, 1 gene, copy number 9 (within-gene range 3–10): GRIN2B.
- chr12:13,582,031–14,255,226, 8 genes, copy number 9 (within-gene range 3–10): AC007535.1, RN7SKP162, AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1.
- chr12:16,188,485–16,277,685, 1 gene, copy number 9: SLC15A5.
- chr12:30,926,428–30,996,602, 1 gene, copy number 9 (within-gene range 7–9): TSPAN11.
- chr12:38,078,529–38,907,430, 14 genes, copy number 12–13 (within-gene range 4–13): AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8.
- chr12:105,173,297–105,396,097, 4 genes, copy number 9: APPL2, C12orf75, AC078874.1, KCCAT198.
- chr12:127,619,336–127,626,267, 2 genes, copy number 9: Y_RNA, AC025252.2.
- chr12:128,267,403–128,707,915, 1 gene, copy number 9 (within-gene range 7–9): TMEM132C.
- chr12:128,399,978–128,439,206, 2 genes, copy number 9: AC023595.1, AC090424.1.
- chr12:131,462,853–131,529,894, 2 genes, copy number 9 (within-gene range 7–9): AC073578.1, AC073578.3.
- chr12:132,083,540–132,083,779, 1 gene, copy number 11: AC137590.2.
- chr12:132,169,823–132,190,997, 3 genes, copy number 9: AC138466.3, LINC02361, AC138466.1.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
